Gene-level copy-number profile of tumor specimen C3N-00550-02 from CPTAC case C3N-00550, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,107 days).
Specimen C3N-00550-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56b51f64-706a-45e5-9629-0f4749890dc8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00550-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/2e71d52f-94d7-4ce1-8bfc-7fbd64d62e28

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 256; copy number 2: 3,656; copy number 3: 3,326; copy number 4: 29,604; copy number 5: 10,627; copy number 6: 6,665; copy number 7: 3,154; copy number 8: 3; copy number 9: 34; copy number 10: 1,035; copy number 12: 5.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:17,579,066–17,797,124, 2 genes: SH3GL2, PABPC1P11.
- chr9:21,278,050–21,368,962, 6 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13.
- chr9:21,802,636–23,438,700, 20 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:24,542,952–26,118,408, 8 genes: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr18:71,588,537–71,588,884, 1 gene: AC090312.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,074 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–62,275,678, 1,035 genes, copy number 10 (broad region; genes not listed).
- chr14:18,333,726–19,131,167, 34 genes, copy number 9 (within-gene range 7–9): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3.
- chr22:15,282,557–15,350,043, 5 genes, copy number 12: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 253. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
